Somatic mutation profile of tumor specimen TCGA-QQ-A5VA-01A (aliquot TCGA-QQ-A5VA-01A-12D-A32I-09) from TCGA case TCGA-QQ-A5VA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.9 years (22,231 days).
Specimen TCGA-QQ-A5VA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af7e33c3-9f25-4ed7-9033-2694fc33f083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5VA-11A (Solid Tissue Normal), aliquot TCGA-QQ-A5VA-11A-11D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c15a4e45-1c6e-4e1c-9d7f-9a033fb4054c

The open-access MAF lists 59 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Nonsense Mutation 6, Splice Site 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEF2C | c.860C>A p.S287* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs777826971, COSV100425377; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKK1 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs763284159, COSV100392876; called by muse, mutect2, varscan2
- ATP6V1E1 | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as COSV99494291; called by muse, mutect2, varscan2
- BCO1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201320081, COSV50731560; called by muse, mutect2, varscan2
- CCDC110 | c.2305C>T p.R769* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs199552759, COSV56873047; called by muse, mutect2, varscan2
- CCDC130 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as rs766170095, COSV99681241; called by muse, mutect2, varscan2
- CCDC198 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV99371259; called by muse, mutect2, varscan2
- CIBAR2 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101608276; called by muse, mutect2, varscan2
- DENND4C | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100991339; called by muse, mutect2
- DENND5B | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100171532; called by muse, mutect2, varscan2
- DVL1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs770156738, COSV66679105; called by muse, mutect2, varscan2
- ESR2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs147382781, COSV50838063; called by muse, mutect2, varscan2
- FAM167A | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99461526; called by muse, mutect2, varscan2
- FAM47C | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 395/533 reads (74%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.583); catalogued as rs149352851, COSV100792276, COSV100792618; called by muse, mutect2, varscan2
- FEZF1 | c.916C>A p.H306N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100484499, COSV100484539; called by muse, mutect2, varscan2
- FLT4 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs184409663, COSV56109268; called by mutect2, varscan2
- GRM7 | c.1194A>T p.K398N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV100736733; called by muse, mutect2, varscan2
- HEMK1 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV99231753; called by muse, mutect2, varscan2
- HTN3 | c.72+1G>T p.X24_splice | Splice Site (SNP) | VAF 8/76 reads (11%) | catalogued as COSV101126178; called by muse, mutect2, varscan2
- HTT | c.7514C>G p.A2505G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100750813; called by muse, mutect2, varscan2
- IFNA16 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs995735386, COSV66510657; called by muse, mutect2, varscan2
- IGHV3-35 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.736); catalogued as rs765476090; called by muse, mutect2, varscan2
- KMT2C | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100064476, COSV100072281; called by muse, mutect2, varscan2
- KRTAP5-3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs1564955311, COSV101294514; called by muse, varscan2
- LUZP4 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.432); catalogued as rs371208058, COSV100904854; called by muse, mutect2, varscan2
- MAGEC1 | c.1359C>A p.Y453* | Nonsense Mutation (SNP) | VAF 25/221 reads (11%) | catalogued as COSV99595777; called by muse, mutect2, varscan2
- MAGOH | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV101012343; called by muse, mutect2, varscan2
- MAPK10 | c.388T>C p.Y130H (on ENST00000359221 / NM_001351625.2; = p.Y168H on NM_002753.5) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100174568; called by muse, mutect2, varscan2
- MTPAP | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV53935954, COSV99554108; called by muse, mutect2, varscan2
- MYT1L | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV101220837, COSV101220946; called by muse, mutect2, varscan2
- NEUROD4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as rs1341073987, COSV54472548; called by muse, mutect2, varscan2
- NLRP1 | c.2109G>C p.W703C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99334276; called by muse, mutect2
- P3H3 | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.942); catalogued as rs1334648311, COSV99301268; called by muse, mutect2
- POLE | c.1666A>G p.I556V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100266866; called by muse, mutect2, varscan2
- SUGP1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as COSV99895121; called by muse, mutect2, varscan2
- TAAR2 | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100907961; called by muse, mutect2
- TTN | c.66661C>T p.H22221Y (on ENST00000591111; = p.H14797Y on NM_003319.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | PolyPhen probably damaging (0.994); catalogued as COSV100615064, COSV60241326; called by muse, mutect2
- VAV1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1176906044, COSV58389301; called by muse, mutect2
- ZNF652 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755040776, COSV62946762; called by muse, mutect2, varscan2
- ZNF808 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs1289909162, COSV100707737; called by muse, mutect2, varscan2
- MTHFD1 | c.552dup p.L185Afs*20 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- SCOC | c.391_411del p.E131_Q137del (on ENST00000608372; = p.E94_Q100del on NM_032547.3) | In Frame Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- AR | c.609C>T p.S203= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV101017927; called by muse, mutect2, varscan2
- CIBAR2 | c.393G>T p.L131= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101608275; called by muse, mutect2, varscan2
- COG4 | c.1501C>T p.L501= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1327397059, COSV100091820; called by mutect2, varscan2
- COL6A2 | c.618C>T p.S206= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1345508446, COSV100153612; called by muse, mutect2
- DMXL2 | c.1950A>G p.R650= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99196410; called by muse, mutect2, varscan2
- EPHA6 | c.2820A>G p.E940= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs780915905, COSV101063086; called by muse, mutect2, varscan2
- FAM47B | c.465C>T p.P155= | Silent (SNP) | VAF 253/330 reads (77%) | catalogued as rs780401613, COSV61452745, COSV61455558; called by muse, mutect2, varscan2
- H3-4 | c.87C>T p.S29= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs764148759, COSV100797390; called by muse, varscan2
- IGHG4 | c.735G>A p.L245= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs759411359; called by muse, mutect2
- KIR3DL2 | c.321G>A p.S107= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs370791268; called by muse, mutect2, varscan2
- OR2M3 | c.792T>C p.S264= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs1351230465, COSV101513436; called by muse, varscan2
- PCDHB13 | c.1749C>A p.G583= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99507334; called by muse, mutect2, varscan2
- PNPLA7 | c.1074G>A p.A358= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV53004656; called by muse, mutect2, varscan2
- UBA3 | c.1170C>G p.T390= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100734695, COSV62739668; called by muse, mutect2, varscan2
- ZFYVE28 | c.756C>T p.D252= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV99342993; called by muse, mutect2, varscan2
- SLCO1B3 | c.-2T>C | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99681517; called by muse, mutect2, varscan2
